FM case AD5939 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/ffb0514c-62a4-4970-b825-d49a0e570550

Female, 65.7 years: Gastrointestinal stromal tumor, NOS (ICD-O-3 8936/1) of the gastrointestinal tract; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
